Somatic mutation profile of tumor specimen TCGA-D7-A6F2-01A (aliquot TCGA-D7-A6F2-01A-12D-A31L-08) from TCGA case TCGA-D7-A6F2, project TCGA-STAD (Stomach Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Tubular adenocarcinoma; Tissue or organ of origin: Fundus of stomach; AJCC pathologic stage: Stage IB; Tumor grade: G3; Age at diagnosis: 62.4 years (22,801 days).
Specimen TCGA-D7-A6F2-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) a4eba615-ed90-4192-98ee-274478960b42.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-D7-A6F2-10A (Blood Derived Normal), aliquot TCGA-D7-A6F2-10A-01D-A31J-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/c4e1fc1b-8fcd-4ca8-a39c-6c707af3fb27

The open-access MAF lists 71 somatic variants for this specimen: 54 protein-altering or splice-affecting, 16 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 52, Silent 16, Nonsense Mutation 1, Intron 1, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.711G>A p.M237I | Missense Mutation (SNP) | VAF 33/45 reads (73%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs587782664, CM011014, COSV52661887, COSV52681050, COSV52751406; ClinVar: uncertain significance / pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ADAMTS14 | c.3587C>T p.T1196M | Missense Mutation (SNP) | VAF 40/68 reads (59%) | SIFT tolerated, low confidence (0.18); PolyPhen benign (0); catalogued as rs369235646; called by muse, mutect2, varscan2
- ARHGAP44 | c.2321T>C p.L774P | Missense Mutation (SNP) | VAF 25/63 reads (40%) | SIFT deleterious, low confidence (0); PolyPhen benign (0); catalogued as COSV52398119, COSV99311368; called by muse, mutect2, varscan2
- C19orf44 | c.1781T>C p.L594P | Missense Mutation (SNP) | VAF 12/21 reads (57%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99550461; called by muse, mutect2, varscan2
- CDH15 | c.1450G>A p.A484T | Missense Mutation (SNP) | VAF 8/21 reads (38%) | SIFT tolerated (0.28); PolyPhen benign (0.043); catalogued as COSV99228744; called by muse, varscan2
- CNGB3 | c.375T>G p.N125K | Missense Mutation (SNP) | VAF 20/620 reads (3%) | SIFT deleterious (0); PolyPhen possibly damaging (0.503); catalogued as COSV100182837; called by muse, mutect2
- CRYBB1 | c.432+2T>G p.X144_splice | Splice Site (SNP) | VAF 12/32 reads (38%) | catalogued as COSV99316161; called by muse, mutect2, varscan2
- DIDO1 | c.6047C>T p.P2016L | Missense Mutation (SNP) | VAF 23/169 reads (14%) | SIFT deleterious (0.01); PolyPhen benign (0.178); catalogued as rs762357648; called by muse, mutect2, varscan2
- DOCK2 | c.822C>A p.N274K | Missense Mutation (SNP) | VAF 6/25 reads (24%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.549); catalogued as COSV99914587; called by muse, mutect2
- DPYSL4 | c.1145C>T p.A382V | Missense Mutation (SNP) | VAF 17/79 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.807); catalogued as rs1378531905, COSV58307562; called by muse, mutect2, varscan2
- DST | c.9187A>G p.I3063V | Missense Mutation (SNP) | VAF 37/78 reads (47%) | SIFT tolerated, low confidence (0.36); PolyPhen benign (0); catalogued as rs770159463, COSV99759128; called by muse, mutect2, varscan2
- EXOC8 | c.847G>A p.A283T | Missense Mutation (SNP) | VAF 33/78 reads (42%) | SIFT tolerated (0.21); PolyPhen benign (0.031); catalogued as COSV99150046; called by muse, mutect2, varscan2
- FAT1 | c.11156T>A p.V3719E | Missense Mutation (SNP) | VAF 7/30 reads (23%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.448); catalogued as COSV101499589; called by muse, mutect2, varscan2
- FUT8 | c.1623A>T p.K541N (on ENST00000360689 / NM_001371534.1; = p.K378N on NM_004480.4) | Missense Mutation (SNP) | VAF 62/133 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV100651634; called by muse, mutect2, varscan2
- GGPS1 | c.542G>C p.G181A | Missense Mutation (SNP) | VAF 14/85 reads (16%) | SIFT tolerated (0.06); PolyPhen benign (0.182); catalogued as COSV99270568; called by muse, mutect2, varscan2
- GNA14 | c.613C>T p.Q205* | Nonsense Mutation (SNP) | VAF 25/241 reads (10%) | catalogued as COSV100503336; called by muse, mutect2, varscan2
- GNPNAT1 | c.419C>A p.T140N | Missense Mutation (SNP) | VAF 22/51 reads (43%) | SIFT deleterious (0); PolyPhen possibly damaging (0.702); catalogued as COSV99369678; called by muse, mutect2, varscan2
- GNPTAB | c.3693G>C p.Q1231H | Missense Mutation (SNP) | VAF 17/89 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs886048849, COSV100172308; ClinVar: uncertain significance; called by muse, varscan2
- GPR149 | c.1154T>C p.V385A | Missense Mutation (SNP) | VAF 6/46 reads (13%) | SIFT tolerated (0.26); PolyPhen benign (0.003); catalogued as rs370473639; called by muse, mutect2, varscan2
- HDGFL1 | c.190G>A p.E64K | Missense Mutation (SNP) | VAF 7/34 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.958); catalogued as COSV100014696; called by muse, mutect2, varscan2
- HECTD4 | c.13034G>T p.C4345F | Missense Mutation (SNP) | VAF 29/251 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV101108310; called by muse, mutect2, varscan2
- HNRNPM | c.319G>A p.A107T | Missense Mutation (SNP) | VAF 52/144 reads (36%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.621); catalogued as COSV100335368, COSV57694589; called by muse, mutect2, varscan2
- HRNR | c.1769G>A p.R590H | Missense Mutation (SNP) | VAF 68/430 reads (16%) | SIFT tolerated (0.37); PolyPhen benign (0); catalogued as rs199645117; called by muse, mutect2, varscan2
- KANK1 | c.2539G>A p.E847K | Missense Mutation (SNP) | VAF 50/132 reads (38%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.958); catalogued as COSV100620042; called by muse, mutect2, varscan2
- KIF23 | c.2279T>G p.I760S | Missense Mutation (SNP) | VAF 4/42 reads (10%) | SIFT tolerated (0.36); PolyPhen benign (0.006); catalogued as COSV99532630; called by muse, mutect2
- KIF26A | c.2419G>A p.D807N | Missense Mutation (SNP) | VAF 12/26 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1483419517, COSV100181428; called by muse, mutect2, varscan2
- KPNA2 | c.67G>C p.D23H | Missense Mutation (SNP) | VAF 35/162 reads (22%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.993); catalogued as rs183061920, COSV100388865, COSV99043029; called by muse, mutect2, varscan2
- LAMA5 | c.3517G>A p.V1173M | Missense Mutation (SNP) | VAF 32/154 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.539); catalogued as rs780809601, COSV53367618; called by muse, mutect2, varscan2
- LRP1B | c.243C>A p.H81Q | Missense Mutation (SNP) | VAF 9/91 reads (10%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.602); catalogued as COSV101259672; called by muse, mutect2
- LRP2 | c.12119G>A p.S4040N | Missense Mutation (SNP) | VAF 47/93 reads (51%) | SIFT deleterious (0.04); PolyPhen benign (0.272); catalogued as rs201753832, COSV99789856; called by muse, mutect2, varscan2
- MAP1B | c.4066C>T p.P1356S | Missense Mutation (SNP) | VAF 10/48 reads (21%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1292063107, COSV99702829; called by muse, mutect2, varscan2
- MAPKAPK2 | c.721G>T p.D241Y | Missense Mutation (SNP) | VAF 24/55 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99686108; called by muse, mutect2, varscan2
- MOB3B | c.197A>G p.D66G | Missense Mutation (SNP) | VAF 40/87 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV99218843; called by muse, mutect2, varscan2
- MXRA5 | c.6446C>T p.T2149M | Missense Mutation (SNP) | VAF 15/17 reads (88%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); catalogued as rs746976020, COSV54236217; called by muse, mutect2, varscan2
- MYH2 | c.3859C>A p.Q1287K | Missense Mutation (SNP) | VAF 9/50 reads (18%) | SIFT deleterious (0.03); PolyPhen benign (0.142); catalogued as COSV99820752; called by muse, mutect2, varscan2
- P2RX3 | c.493A>C p.M165L | Missense Mutation (SNP) | VAF 28/72 reads (39%) | SIFT tolerated (0.93); PolyPhen possibly damaging (0.536); catalogued as COSV99628877; called by muse, mutect2, varscan2
- P2RX3 | c.494T>A p.M165K | Missense Mutation (SNP) | VAF 28/74 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.947); catalogued as COSV99628878; called by muse, mutect2, varscan2
- PCDHGA3 | c.2333C>T p.T778M | Missense Mutation (SNP) | VAF 39/175 reads (22%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.148); catalogued as rs749000978, COSV99544911; called by muse, varscan2
- PGAP4 | c.569A>C p.D190A | Missense Mutation (SNP) | VAF 5/71 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100877869; called by muse, mutect2
- PI15 | c.608G>A p.R203H | Missense Mutation (SNP) | VAF 16/129 reads (12%) | SIFT tolerated (0.4); PolyPhen benign (0.028); catalogued as rs774377290, COSV99478203; called by muse, mutect2, varscan2
- PLXNB3 | c.3853C>T p.R1285W | Missense Mutation (SNP) | VAF 3/27 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV62801672; called by muse, mutect2
- PPL | c.3247C>T p.L1083F | Missense Mutation (SNP) | VAF 16/279 reads (6%) | SIFT tolerated (0.22); PolyPhen benign (0.372); catalogued as COSV99278500; called by muse, mutect2
- PRDM15 | c.2690C>T p.T897M | Missense Mutation (SNP) | VAF 4/18 reads (22%) | SIFT deleterious (0.03); PolyPhen benign (0.079); catalogued as rs149309111; called by mutect2, varscan2
- PRDM16 | c.2260G>A p.E754K | Missense Mutation (SNP) | VAF 38/111 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.678); catalogued as rs369599647, COSV54611655; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- PTPRJ | c.3107A>G p.D1036G | Missense Mutation (SNP) | VAF 15/77 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV101395706; called by muse, varscan2
- PXDN | c.2198C>T p.S733L | Missense Mutation (SNP) | VAF 16/188 reads (9%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as rs372430177, COSV99413016; called by muse, mutect2
- RTL3 | c.1313G>A p.R438H | Missense Mutation (SNP) | VAF 32/44 reads (73%) | SIFT tolerated (0.34); PolyPhen benign (0); catalogued as rs369311059, COSV58183086; called by muse, mutect2, varscan2
- SFMBT1 | c.2407C>T p.R803W | Missense Mutation (SNP) | VAF 3/47 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs867253711, COSV56256226; called by muse, mutect2
- TFAP2C | c.541G>A p.D181N | Missense Mutation (SNP) | VAF 11/94 reads (12%) | SIFT tolerated (0.12); PolyPhen benign (0.277); catalogued as COSV52372837, COSV99571697; called by muse, mutect2, varscan2
- TNN | c.1441G>T p.D481Y | Missense Mutation (SNP) | VAF 6/48 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV99512751; called by muse, mutect2, varscan2
- TNXB | c.6344C>T p.T2115M (on ENST00000647633; = p.T1868M on NM_019105.8 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 11/41 reads (27%) | SIFT tolerated (0.18); PolyPhen benign (0.046); catalogued as rs1188559992, COSV64472694; called by muse, mutect2
- TRPC1 | c.185T>A p.M62K | Missense Mutation (SNP) | VAF 4/38 reads (11%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.482); catalogued as COSV99859232; called by muse, mutect2
- TTC27 | c.595C>T p.R199C | Missense Mutation (SNP) | VAF 16/189 reads (8%) | SIFT tolerated (0.1); PolyPhen benign (0.027); catalogued as rs773452993, COSV100513460; called by muse, mutect2
- TTN | c.42292G>C p.G14098R (on ENST00000591111; = p.G6674R on NM_003319.4) | Missense Mutation (SNP) | VAF 22/135 reads (16%) | PolyPhen probably damaging (0.975); catalogued as COSV100625958; called by muse, mutect2, varscan2
- AMER1 | c.1386A>G p.E462= | Silent (SNP) | VAF 4/28 reads (14%) | catalogued as COSV57659171; called by muse, mutect2
- CCDC33 | c.612G>A p.R204= | Silent (SNP) | VAF 3/42 reads (7%) | called by muse, mutect2
- CLDN3 | c.600G>A p.A200= | Silent (SNP) | VAF 40/95 reads (42%) | catalogued as rs1554626616, COSV101230856; called by muse, mutect2, varscan2
- COL12A1 | c.6021G>A p.L2007= | Silent (SNP) | VAF 29/46 reads (63%) | catalogued as COSV100486360; called by muse, mutect2, varscan2
- IPPK | c.186C>A p.V62= | Silent (SNP) | VAF 11/158 reads (7%) | catalogued as COSV99845811; called by muse, mutect2
- KLHDC8A | c.108C>T p.I36= | Silent (SNP) | VAF 11/74 reads (15%) | catalogued as rs996937288, COSV65679021; called by muse, mutect2, varscan2
- LLGL2 | c.1614G>A p.A538= | Silent (SNP) | VAF 6/47 reads (13%) | catalogued as rs370262429; called by muse, mutect2, varscan2
- OGG1 | c.1044G>A p.G348= | Silent (SNP) | VAF 29/52 reads (56%) | catalogued as COSV99844901; called by muse, mutect2, varscan2
- OR52B2 | c.630C>T p.I210= | Silent (SNP) | VAF 20/51 reads (39%) | catalogued as COSV101603962; called by muse, mutect2, varscan2
- OR9Q2 | c.222G>A p.S74= | Silent (SNP) | VAF 27/78 reads (35%) | catalogued as rs760143408, COSV61113093; called by muse, mutect2, varscan2
- SCGB2A1 | c.105C>T p.S35= | Silent (SNP) | VAF 34/113 reads (30%) | catalogued as rs745608043, COSV99793774; called by muse, mutect2, varscan2
- SGCE | c.801G>A p.P267= (on ENST00000647096; = p.P231= on NM_003919.3) | Silent (SNP) | VAF 10/40 reads (25%) | catalogued as rs757206832, COSV56018366; ClinVar: likely benign; called by muse, mutect2, varscan2
- SNTG1 | c.1323T>G p.G441= | Silent (SNP) | VAF 47/149 reads (32%) | catalogued as COSV99385483; called by muse, mutect2, varscan2
- SRCAP | c.2775C>T p.T925= | Silent (SNP) | VAF 124/440 reads (28%) | catalogued as rs564356034, COSV99351077; called by muse, mutect2, varscan2
- TMEM63C | c.2316G>A p.P772= | Silent (SNP) | VAF 90/275 reads (33%) | catalogued as rs529233834, COSV100029700; called by muse, mutect2, varscan2
- TOMM20 | c.6G>C p.V2= | Silent (SNP) | VAF 40/173 reads (23%) | catalogued as COSV100784033; called by muse, mutect2, varscan2
- NAP1L4 | c.606+801A>C | Intron (SNP) | VAF 17/220 reads (8%) | catalogued as COSV101000742; called by muse, mutect2
